Somatic mutation profile of tumor specimen TCGA-AA-A02F-01A (aliquot TCGA-AA-A02F-01A-01W-A00E-09) from TCGA case TCGA-AA-A02F, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.6 years (25,051 days).
Specimen TCGA-AA-A02F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dc400d3-83fd-4a65-b4e9-316596708fb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02F-10A (Blood Derived Normal), aliquot TCGA-AA-A02F-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01321d3-f563-47e0-9136-2aa1ea171818

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 18, Frame Shift Ins 3, Nonsense Mutation 3, Splice Site 2, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 44/119 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 16/20 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM29 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 125/154 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV63668027; called by muse, mutect2, varscan2
- AKAP12 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs552053449, COSV53570956; called by muse, mutect2, varscan2
- AKAP3 | c.1847A>C p.K616T | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); catalogued as COSV57420470; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 82/129 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- APOB | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.16); catalogued as COSV51945398, COSV51958163; called by muse, mutect2, varscan2
- CFTR | c.1085A>C p.Y362S | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV50097309; called by muse, mutect2, varscan2
- CNGB1 | c.2006G>T p.W669L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV51906906; called by muse, mutect2
- CNTNAP2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62208430, COSV62223787; called by muse, mutect2, varscan2
- CRAMP1 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV53530792; called by muse, mutect2, varscan2
- CRYL1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV53421327; called by muse, mutect2, varscan2
- CUX2 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55647487; called by muse, mutect2, varscan2
- FAM47C | c.2883G>C p.K961N | Missense Mutation (SNP) | VAF 84/106 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV100792280, COSV63730284; called by muse, mutect2, varscan2
- FANCD2 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 23/156 reads (15%) | catalogued as rs368848371; called by muse, mutect2, varscan2
- GRIA1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1380820240, COSV53589953; called by muse, mutect2, varscan2
- HNRNPA3 | c.1005T>A p.Y335* | Nonsense Mutation (SNP) | VAF 59/133 reads (44%) | catalogued as COSV66821164; called by muse, mutect2, varscan2
- HUWE1 | c.11172G>C p.L3724F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53363274; called by muse, mutect2, varscan2
- IGDCC3 | c.2435C>T p.S812L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs200034167, COSV60080194; called by muse, mutect2
- LAMA1 | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV67544175; called by muse, mutect2, varscan2
- LAMB1 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs267601228, COSV55963509; called by muse, mutect2, varscan2
- MAPK9 | c.1078G>C p.V360L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV58126044; called by muse, mutect2, varscan2
- MKLN1 | c.1893A>T p.L631F | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV61762739; called by muse, mutect2, varscan2
- MRGPRX1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs202061081; called by muse, mutect2, varscan2
- NCKAP5 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1328884638, COSV58474206; called by muse, mutect2, varscan2
- NLRC5 | c.3574C>T p.R1192W | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs370896719; called by muse, mutect2, varscan2
- NOL9 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV60230154; called by muse, mutect2, varscan2
- NOM1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV51982386, COSV99315627; called by muse, varscan2
- NRXN1 | c.1768_1769insA p.S590Yfs*14 | Frame Shift Ins (INS) | VAF 65/178 reads (37%) | catalogued as COSV58491299; called by mutect2, pindel, varscan2
- OR2M2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 447/971 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs142698993; called by muse, mutect2, varscan2
- OR52J3 | c.822C>G p.H274Q | Missense Mutation (SNP) | VAF 238/739 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66746397, COSV66747764; called by muse, mutect2, varscan2
- PKIA | c.152-1G>C p.X51_splice | Splice Site (SNP) | VAF 76/160 reads (48%) | catalogued as rs756532119, COSV61916659; called by muse, mutect2, varscan2
- SIPA1L1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781073711, COSV62173479; called by muse, mutect2, varscan2
- SLC28A2 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61665241; called by muse, mutect2, varscan2
- SPON1 | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV59967999; called by muse, mutect2, varscan2
- TMEM132B | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs757921642, COSV54768467; called by muse, mutect2, varscan2
- TTN | c.65405G>T p.R21802L (on ENST00000591111; = p.R14378L on NM_003319.4) | Missense Mutation (SNP) | VAF 19/171 reads (11%) | PolyPhen benign (0.059); catalogued as COSV60264572; called by muse, mutect2
- VPS18 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV55032220; called by muse, mutect2, varscan2
- ZDHHC21 | c.663T>G p.D221E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66615312; called by muse, mutect2
- ACVR2A | c.1331_1333del p.Y444del | In Frame Del (DEL) | VAF 130/338 reads (38%) | called by pindel, varscan2
- APC | c.1434dup p.L479Ifs*6 | Frame Shift Ins (INS) | VAF 59/159 reads (37%) | called by mutect2, pindel, varscan2
- APC | c.3937dup p.T1313Nfs*2 | Frame Shift Ins (INS) | VAF 119/293 reads (41%) | called by mutect2, pindel, varscan2
- KCNMB1 | c.307-2A>T p.X103_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- RB1 | c.1587_1588del p.Y529* | Frame Shift Del (DEL) | VAF 32/165 reads (19%) | called by mutect2, pindel, varscan2
- TNFRSF11B | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TRMT1 | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2
- AK9 | c.3144C>T p.N1048= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as rs151316525; called by muse, mutect2, varscan2
- CACNA2D3 | c.1176C>A p.I392= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV55580643; called by muse, mutect2
- CAVIN2 | c.1239C>T p.P413= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs776133100, COSV58425826; called by mutect2, varscan2
- CDH12 | c.2280A>G p.E760= | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as COSV66390541; called by muse, mutect2
- CDK8 | c.300T>A p.A100= | Silent (SNP) | VAF 110/369 reads (30%) | catalogued as COSV67423072; called by muse, mutect2, varscan2
- CRISP1 | c.99C>T p.L33= | Silent (SNP) | VAF 187/428 reads (44%) | catalogued as rs776060725, COSV59992811; called by muse, mutect2, varscan2
- GTF3C2 | c.495T>A p.S165= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV53128697; called by muse, mutect2, varscan2
- IER3IP1 | c.213C>T p.N71= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as COSV56507112; called by muse, mutect2, varscan2
- KCNB2 | c.2040C>A p.A680= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- MAGED1 | c.1434G>A p.L478= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- MAP2 | c.2808C>T p.S936= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as rs570922955, COSV52307403; called by muse, mutect2, varscan2
- MKI67 | c.8268A>C p.P2756= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- NDRG2 | c.366C>T p.D122= (on ENST00000298687 / NM_001354570.1; = p.D108= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53873588; called by muse, mutect2, varscan2
- NR3C1 | c.1572G>A p.T524= | Silent (SNP) | VAF 262/558 reads (47%) | catalogued as rs138266608, COSV51546745; called by muse, mutect2, varscan2
- SPEF2 | c.963C>T p.A321= | Silent (SNP) | VAF 78/220 reads (35%) | catalogued as COSV56800406; called by muse, mutect2, varscan2
- SYNE2 | c.4002A>G p.T1334= | Silent (SNP) | VAF 107/255 reads (42%) | catalogued as COSV59969294; called by muse, mutect2, varscan2
- SZT2 | c.8697G>A p.S2899= (on ENST00000634258 / NM_001365999.1; = p.S2842= on NM_015284.4) | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs780388714, COSV65174364; called by muse, mutect2, varscan2
- TSHZ2 | c.108C>T p.S36= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs752591081, COSV61591078; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85627C>T | Intron (SNP) | VAF 68/91 reads (75%) | catalogued as rs774334691, COSV72275878; called by muse, mutect2, varscan2
